Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GF, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GF-01A (Primary Tumor).

[page 1 of 4]
Subject ID

GROSS:

Specimen state: Fresh

Procedure: Total gastrectomy

Organ:

Stomach

Greater curvature 21.0 cm

Lesser curvature 13.5 cm

Proximal resection margin 1.3 cm

Distal resection margin 5.5 cm

Duodenum 2.5 cm in continuity

Lesion: A gastric mass

Size: 8.0 x 6.5 cm

Site: Antrum

Tumor type: AGC (Borrmann type III)

Safety margin:

Proximal: 1.8 cm

Distal: 3.8 cm

Gross serosal invasion: Bulging but smooth

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4 and TB, tumor and surrounding tissue x 5

B and NB, body mucosa x 2

P and PRM, proximal resection margin x 2

D, distal resection margin x 1

LN1-2, superior gastric lymph nodes x 2

LN3-5, inferior gastric lymph nodes x 3

LN6, '1' lymph nodes x 1

LN7, '2' lymph nodes x 1

LN8, '4sa' lymph nodes x 1

LN9, '4sb' lymph nodes x 1

LN10, '5' lymph nodes x 1

LN11-12, '6' lymph nodes x 2

LN13, '7' lymph nodes x 1

LN14, '8' lymph nodes x 1

LN15, '9' lymph nodes x 1

ICD-0-3

adenocarcinoma, tubular 8211/3

Site: stomach, antrum C16.3

fw 9/27/12

[page 2 of 4]
LN16, '10' lymph nodes x 1
LN17, '11p' lymph nodes x 1
LN18, '11d' lymph nodes x 1
LN19, '12' lymph nodes x 1

MICROSCOPIC:

Tumor type: Adenocarcinoma

Differentiation: Moderately differentiated

Depth of tumor invasion:

T3: Tumor penetrates subserosal connective tissue without invasion of
visceral peritoneum or adjacent structures

Margins: Proximal resection margin (-)

Distal resection margin (-)

Lauren classification: Intestinal

Ming classification (Growth pattern): Infiltrative

Lymphoid reaction: Present

Lymphovascular invasion: Present

Venous (large vessel) invasion: Absent

Perineural invasion: Present

Lymph node metastasis: Absent (0/81)

Pathologic stage: pT3N0Mx (AJCC 7th edition)

DIAGNOSIS:

Stomach, total gastrectomy:

Adenocarcinoma, moderately differentiated, infiltrating
(Advanced gastric cancer)

<Addendum>

Final diagnosis: Stomach Intestinal Adenocarcinoma, Tubular Type

Lymph node, perigastric, total gastrectomy:

Superior gastric: No tumor present (0/15)

Inferior gastric: No tumor present (0/20)

Lymph node, regional, biopsy:

Labeled as '1': No tumor present (0/1)

Labeled as '2': No tumor present (0/5)

Labeled as '4sa': No tumor present (0/1)

Labeled as '4sb': No tumor present (0/5)

[page 3 of 4]
Labeled as '5': No lymphoid tissue
Labeled as '6': No tumor present (0/13)
Labeled as '7': No tumor present (0/1)
Labeled as '8': No tumor present (0/1)
Labeled as '9': No tumor present (0/3)
Labeled as '10': No tumor present (0/1)
Labeled as '11p': No tumor present (0/6)
Labeled as '11d': No tumor present (0/1)
Labeled as '12': No tumor present (0/8)

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Intestinal Adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Intestinal Adenocarcinoma, Tubular Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	In addendum, we clarified that this is an intestinal adenocarcinoma, tubular type	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 9edd06b8-6781-4dcf-bb8b-a13c413e7472 (TCGA-HU-A4GF.47E2870C-F7AD-443B-8935-6F0D3520F298.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).